Somatic mutation profile of tumor specimen TCGA-BR-6457-01A (aliquot TCGA-BR-6457-01A-21D-1800-08) from TCGA case TCGA-BR-6457, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 69.5 years (25,396 days).
Specimen TCGA-BR-6457-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e29148b9-bcf2-44bd-9d12-5ff9c2bc3c11.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-6457-10A (Blood Derived Normal), aliquot TCGA-BR-6457-10A-01D-1800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/726b3fda-738f-4792-b27e-d447b0001c35

The open-access MAF lists 109 somatic variants for this specimen: 85 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 22, Frame Shift Del 3, Nonsense Mutation 2, RNA 1, 5'Flank 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 16/98 reads (16%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.886T>G p.F296V | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.598); catalogued as COSV51702528, COSV51719981; called by muse, mutect2, varscan2
- ACBD4 | c.137A>G p.Y46C | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58851148; called by muse, mutect2, varscan2
- ADCY8 | c.523T>G p.L175V | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT tolerated (0.62); PolyPhen benign (0.074); catalogued as COSV53900685; called by muse, mutect2
- ADGRV1 | c.4685G>T p.R1562I | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.241); catalogued as COSV67980800; called by muse, mutect2
- ANO4 | c.2803C>T p.R935C (on ENST00000392977 / NM_001286615.2; = p.R900C on NM_178826.4) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs139827573, COSV54585067; called by mutect2, varscan2
- APMAP | c.410C>T p.S137L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.023); catalogued as rs371061783; called by mutect2, varscan2
- AQP8 | c.602+1G>A p.X201_splice | Splice Site (SNP) | VAF 5/23 reads (22%) | catalogued as rs1304445444, COSV54844491; called by muse, mutect2
- ARL13B | c.723T>G p.D241E (on ENST00000394222 / NM_001174150.2; = p.D134E on NM_144996.4) | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57396983; called by muse, mutect2
- ATAT1 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs374141920; called by muse, mutect2, varscan2
- C8A | c.613T>C p.Y205H | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV63483408; called by muse, mutect2, varscan2
- CACNA1C | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as rs969789637, COSV59704502; called by mutect2, varscan2
- CCDC73 | c.2974G>A p.E992K | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV58796521; called by muse, mutect2, varscan2
- CDK13 | c.3389A>T p.N1130I | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99476082; called by muse, mutect2, varscan2
- CLIP3 | c.916_918del p.K306del | In Frame Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs769218636; called by mutect2, pindel, varscan2
- CPAMD8 | c.5057C>T p.S1686L (on ENST00000651564; = p.S1639L on NM_015692.5) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.207); catalogued as rs554961997, COSV71596075; called by mutect2, varscan2
- CPS1 | c.1643A>C p.Q548P | Missense Mutation (SNP) | VAF 17/168 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV51805047; called by muse, mutect2, varscan2
- CSMD3 | c.8212G>A p.E2738K | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.269); catalogued as rs1283805790, COSV52092220; called by muse, mutect2, varscan2
- CSMD3 | c.8021G>T p.C2674F (on ENST00000297405 / NM_001363185.1; = p.C2570F on NM_052900.3) | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52130924; called by muse, mutect2
- CSMD3 | c.7719A>C p.E2573D (on ENST00000297405 / NM_001363185.1; = p.E2469D on NM_052900.3) | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.013); catalogued as COSV52130939; called by muse, mutect2
- DCAF1 | c.2562A>G p.I854M | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.778); catalogued as COSV60041508; called by muse, mutect2
- DDX49 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763850904, COSV55355227; called by muse, mutect2
- DLC1 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.375); catalogued as rs150701452; called by muse, mutect2, varscan2
- DOCK10 | c.3065C>A p.S1022Y | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV51360279; called by muse, mutect2
- DSEL | c.1181C>T p.T394I | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59490179; called by muse, mutect2, varscan2
- EEF1A2 | c.454G>A p.V152M | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV53205168; called by muse, mutect2
- FAT4 | c.3506G>A p.R1169Q | Missense Mutation (SNP) | VAF 18/225 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs750169762, COSV67882818; called by muse, mutect2
- FLG2 | c.2629A>T p.S877C | Missense Mutation (SNP) | VAF 74/269 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.468); catalogued as COSV101165778, COSV66167293; called by muse, mutect2, varscan2
- FMN2 | c.4886A>C p.N1629T | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as COSV60422206; called by muse, mutect2
- GLI3 | c.4055C>A p.S1352* | Nonsense Mutation (SNP) | VAF 7/51 reads (14%) | catalogued as COSV67886410; called by muse, mutect2, varscan2
- GPC6 | c.953A>G p.K318R | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.649); catalogued as rs894014798, COSV65503315; called by muse, mutect2, varscan2
- GPRC5C | c.881C>A p.T294K (on ENST00000652232; = p.T249K on NM_018653.4) | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.36); catalogued as COSV61236042; called by muse, mutect2, varscan2
- HELB | c.3122G>T p.C1041F | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.28); catalogued as COSV56072883; called by muse, mutect2
- KDR | c.2072C>A p.S691Y | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as COSV55760573; called by muse, mutect2
- KIAA1109 | c.11255C>T p.T3752M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.212); catalogued as rs371627735; called by muse, mutect2, varscan2
- LDB2 | c.606C>G p.N202K | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58764878; called by muse, mutect2, varscan2
- LGALS8 | c.692A>T p.N231I (on ENST00000341872; = p.N273I on NM_006499.4) | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53023969; called by muse, mutect2
- LPA | c.3920A>G p.Q1307R | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.139); catalogued as COSV60298880, COSV60303830; called by muse, mutect2
- LYPD4 | c.92A>G p.E31G | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as COSV58027557; called by muse, mutect2
- MCTP2 | c.2092T>G p.L698V | Missense Mutation (SNP) | VAF 13/279 reads (5%) | SIFT tolerated (0.7); PolyPhen benign (0.058); catalogued as COSV63292379; called by muse, mutect2
- MUC16 | c.34158A>C p.E11386D | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.103); catalogued as COSV67442926; called by muse, mutect2, varscan2
- MYBL2 | c.2083C>T p.R695W | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1195606879, COSV53828562; called by muse, mutect2, varscan2
- MYRF | c.1057T>C p.W353R (on ENST00000278836 / NM_001127392.3; = p.W344R on NM_013279.4) | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53886962; called by muse, mutect2, varscan2
- NPY1R | c.977A>C p.N326T | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56713773; called by muse, mutect2
- NUP153 | c.2942T>G p.F981C | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50446027; called by muse, mutect2, varscan2
- OR2F1 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 23/333 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs141187562; called by muse, mutect2
- OR2M7 | c.442T>C p.S148P | Missense Mutation (SNP) | VAF 12/357 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58738331; called by muse, mutect2
- OR2T12 | c.887A>C p.K296T | Missense Mutation (SNP) | VAF 18/265 reads (7%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.821); catalogued as COSV58776831; called by muse, mutect2
- OR4C13 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs571287901, COSV73648677; called by muse, mutect2, varscan2
- OR5D13 | c.217T>G p.F73V | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV62333075; called by muse, mutect2
- PCDH17 | c.1773C>A p.D591E | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV64972779; called by mutect2, varscan2
- PCED1A | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as COSV62313486; called by muse, mutect2, varscan2
- PFKFB4 | c.239G>A p.R80Q | Missense Mutation (SNP) | VAF 10/86 reads (12%) | PolyPhen probably damaging (0.993); catalogued as rs1335156706, COSV51680113, COSV99219681; called by muse, mutect2, varscan2
- PRDM9 | c.631T>G p.F211V | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV57003742; called by muse, mutect2, varscan2
- PRSS55 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 213/383 reads (56%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1342074084, COSV60807952; called by muse, mutect2, varscan2
- RMDN1 | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 65/250 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.607); catalogued as COSV68830253; called by muse, mutect2, varscan2
- RP1 | c.4982C>G p.S1661C | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV104377563, COSV55112671; called by muse, mutect2
- SDC2 | c.243T>G p.S81R | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.93); catalogued as COSV56226517; called by muse, mutect2
- SHOC1 | c.2974G>A p.E992K | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV59498878; called by muse, mutect2, varscan2
- SLC25A46 | c.991C>G p.L331V | Missense Mutation (SNP) | VAF 29/339 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV63506603; called by muse, mutect2
- SLC36A4 | c.111T>A p.D37E | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.097); catalogued as COSV58395523; called by muse, mutect2, varscan2
- SLCO1B3 | c.755C>A p.S252Y | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as COSV53932901, COSV53934334; called by muse, mutect2, varscan2
- SLCO1B3 | c.1725G>C p.Q575H | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53934343; called by muse, varscan2
- SMAD9 | c.1039G>T p.A347S (on ENST00000379826 / NM_001127217.3; = p.A310S on NM_005905.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.674); catalogued as COSV63204384; called by muse, varscan2
- SNTN | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.286); catalogued as rs1169512621, COSV59538659; called by muse, mutect2, varscan2
- SPART | c.1781C>A p.A594E | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62084155, COSV62086122; called by muse, mutect2, varscan2
- SPATA18 | c.206A>T p.D69V | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.165); catalogued as COSV54642571; called by muse, mutect2, varscan2
- STAT3 | c.994C>T p.H332Y | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as CM085729, COSV52885205; called by muse, mutect2
- TAF9B | c.394T>A p.L132I | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV59370959; called by muse, mutect2, varscan2
- TMEM131 | c.4180C>T p.P1394S | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.024); catalogued as rs1337160971, COSV51772004; called by muse, mutect2, varscan2
- TPCN1 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 52/377 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs1050374706, COSV59233549; called by muse, mutect2, varscan2
- TUSC3 | c.196T>G p.F66V | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV65879134, COSV65887519; called by muse, mutect2, varscan2
- URI1 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs778158912, COSV56348617; called by muse, mutect2, varscan2
- VPS51 | c.767A>G p.E256G | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV54206487; called by muse, mutect2
- WAPL | c.2447G>A p.R816Q | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV53933325; called by muse, mutect2
- WNT2B | c.539G>A p.R180H (on ENST00000369684 / NM_024494.3; = p.R161H on NM_004185.4) | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.086); catalogued as rs35058556; called by muse, mutect2, varscan2
- ZDHHC8 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs374875529; called by muse, mutect2, varscan2
- ZFPL1 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs747733761, COSV51868886, COSV51869999; called by muse, mutect2, varscan2
- ZFYVE1 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759215529, COSV59610270; called by muse, mutect2, varscan2
- ZMAT4 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.031); catalogued as COSV52693136; called by muse, mutect2
- AGAP4 | c.143C>G p.A48G | Missense Mutation (SNP) | VAF 19/321 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.364); called by muse, mutect2
- MUC6 | c.2745_2751del p.I916Gfs*40 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- OR2K2 | c.287_288del p.S96Ffs*54 (on ENST00000374428; = p.S67Ffs*54 on NM_205859.2) | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | called by pindel, varscan2
- PHLDA1 | c.530_534del p.E177Afs*238 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | called by mutect2, varscan2
- TRAJ31 | c.9C>A p.N3K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | called by muse, varscan2
- ADAMTSL1 | c.912G>A p.T304= | Silent (SNP) | VAF 9/118 reads (8%) | catalogued as rs890950152, COSV52810937; called by muse, mutect2
- AHNAK | c.1986C>T p.P662= | Silent (SNP) | VAF 28/225 reads (12%) | catalogued as COSV57207379; called by muse, mutect2, varscan2
- ANGPT1 | c.969T>A p.G323= | Silent (SNP) | VAF 11/147 reads (7%) | catalogued as COSV52434224; called by muse, mutect2
- FAM81B | c.750C>T p.P250= | Silent (SNP) | VAF 16/160 reads (10%) | catalogued as rs201492691; called by muse, mutect2, varscan2
- FITM1 | c.546C>T p.T182= | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as rs139067370; called by muse, mutect2, varscan2
- GRIK4 | c.1581C>T p.R527= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as rs201601103, COSV70799662; called by muse, mutect2, varscan2
- HSPG2 | c.4773C>T p.C1591= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs764396560, COSV65969948; called by muse, mutect2, varscan2
- KMT2C | c.2760A>G p.V920= | Silent (SNP) | VAF 11/121 reads (9%) | catalogued as COSV51419828; called by muse, mutect2
- OBSCN | c.4146G>A p.T1382= | Silent (SNP) | VAF 16/137 reads (12%) | catalogued as rs368928612, COSV52761496; called by muse, mutect2, varscan2
- POLD2 | c.322C>T p.L108= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV56256222; called by muse, mutect2, varscan2
- PXDN | c.3159C>T p.Y1053= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs773257713, COSV53229100; called by muse, mutect2
- QARS1 | c.582T>G p.A194= | Silent (SNP) | VAF 47/340 reads (14%) | catalogued as COSV60274411; called by muse, mutect2, varscan2
- RGS3 | c.3267C>T p.A1089= (on ENST00000350696 / NM_001282923.2; = p.A808= on NM_130795.4) | Silent (SNP) | VAF 5/92 reads (5%) | catalogued as COSV59512992; called by muse, mutect2
- SLC13A1 | c.1194T>C p.L398= | Silent (SNP) | VAF 25/254 reads (10%) | catalogued as COSV52009297; called by muse, mutect2
- SLC25A21 | c.456T>G p.G152= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV58717323; called by muse, mutect2, varscan2
- SLC25A29 | c.63G>A p.P21= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs376570974; called by muse, mutect2, varscan2
- TASOR2 | c.306G>A p.G102= | Silent (SNP) | VAF 13/130 reads (10%) | catalogued as COSV100051015; called by muse, mutect2, varscan2
- UNC13B | c.1359C>T p.D453= | Silent (SNP) | VAF 20/152 reads (13%) | catalogued as rs368947711; called by muse, mutect2, varscan2
- YLPM1 | c.1785C>T p.S595= | Silent (SNP) | VAF 15/156 reads (10%) | called by muse, mutect2, varscan2
- ZNF219 | c.1404G>C p.G468= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV53878922; called by muse, mutect2, varscan2
- ZNF300 | c.1611G>A p.P537= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as rs140923053; called by muse, mutect2, varscan2
- ZNF827 | c.1689A>G p.A563= | Silent (SNP) | VAF 9/128 reads (7%) | catalogued as COSV65225647; called by muse, mutect2
- AL590867.2 | n.96C>T | RNA (SNP) | VAF 16/168 reads (10%) | catalogued as rs972701104; called by muse, mutect2
- CLLU1 | chr12:92421165 G>A | 5'Flank (SNP) | VAF 13/114 reads (11%) | catalogued as rs1359577570, COSV65902894; called by muse, mutect2
